Surgical pathology report (de-identified scan), TCGA case TCGA-CD-A4MJ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-A4MJ-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report

(For Collection of Cancerous Tissue)

1CD-0-3

adenocarcinoma, NOS 8/40/3

LQCF Site: stomach, fundus C16.1
Path stomach, lesser curvature C16.5

10/3/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height 1m74	Marital Status ☐ Single ☒ Married ☐ Divorced ☐ Widow	Race METAWANSE	Temperature
Gender ☒ Male ☐ Female	Weight 64 kg		Blood Pressure 12/8	Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; blood in the stool.
Symptoms: Weight loss - weakness.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1/2 p / day	30 (yrs)	Still Smokes (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		3 drinks/day	30 (yrs)	2 years ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	An ulceration was found in the lesser curvature	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Stomach Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: IB		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach Tumor	lesser curvature	5 x 4 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: IB			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	5 x 4 x 2 cm	lesser curvature	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₂	N ₀	M ₀	Stage: IB
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution					Structural Pattern						
	+	-							+	-	
Diffuse					Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation:	Well	Moderate	Poor
----------------------------------	------	----------	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	

Nuclear Grade:				
-----------------------	--	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma of the Stomach
(well differentiated) pT2 No Mo Stage I B **Grade:** 1

Comments:

Principal Investigator

Pathologist

Date

[page 6 of 6]
Microscopic Appearance:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse				Streaming			
Mosaic		X	X	Storiform			
Necrosis		X	X	Fibrosis			
Lymphocytic Infiltration		X	X	Palisading			
Vascular Invasion				Cystic Degeneration			
Clusterized		X	X	Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Pseudomoma/Calcification			

Histologic Features:											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	Y		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	Y		Fibroblast			Small Cell		
Keratin			Secretion	Y		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	Y		Lipoblast			Inflam. Cell		
Pearl			Gland formation	Y		Myoblast			Plasma Cell		
Otherwise Specified: D ₁ 50% D ₂ 50% D ₃ 50% D ₄ 50%											

Well	Moderately	Poor
	☒	

3. Nuclear Atypia:				
Nuclear Appearance	0	1	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade				

Histological Diagnosis: Adenocarcinoma NOS, G2

Comments:

Date _____

Director, Research Pathology

*** (INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR)**

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

	Yes	No
21. Site discrepancy		X
22. Tumor Site discrepancy		X
23. Tumor Site discrepancy		X
24. Tumor Site discrepancy		X
25. Tumor Site discrepancy		X
26. Tumor Site discrepancy		X
27. Tumor Site discrepancy		X
28. Tumor Site discrepancy		X
29. Tumor Site discrepancy		X
30. Tumor Site discrepancy		X
31. Tumor Site discrepancy		X
32. Tumor Site discrepancy		X
33. Tumor Site discrepancy		X
34. Tumor Site discrepancy		X
35. Tumor Site discrepancy		X
36. Tumor Site discrepancy		X
37. Tumor Site discrepancy		X
38. Tumor Site discrepancy		X
39. Tumor Site discrepancy		X
40. Tumor Site discrepancy		X
41. Tumor Site discrepancy		X
42. Tumor Site discrepancy		X
43. Tumor Site discrepancy		X
44. Tumor Site discrepancy		X
45. Tumor Site discrepancy		X
46. Tumor Site discrepancy		X
47. Tumor Site discrepancy		X
48. Tumor Site discrepancy		X
49. Tumor Site discrepancy		X
50. Tumor Site discrepancy		X
51. Tumor Site discrepancy		X
52. Tumor Site discrepancy		X
53. Tumor Site discrepancy		X
54. Tumor Site discrepancy		X
55. Tumor Site discrepancy		X
56. Tumor Site discrepancy		X
57. Tumor Site discrepancy		X
58. Tumor Site discrepancy		X
59. Tumor Site discrepancy		X
60. Tumor Site discrepancy		X
61. Tumor Site discrepancy		X
62. Tumor Site discrepancy		X
63. Tumor Site discrepancy		X
64. Tumor Site discrepancy		X
65. Tumor Site discrepancy		X
66. Tumor Site discrepancy		X
67. Tumor Site discrepancy		X
68. Tumor Site discrepancy		X
69. Tumor Site discrepancy		X
70. Tumor Site discrepancy		X
71. Tumor Site discrepancy		X
72. Tumor Site discrepancy		X
73. Tumor Site discrepancy		X
74. Tumor Site discrepancy		X
75. Tumor Site discrepancy		X
76. Tumor Site discrepancy		X
77. Tumor Site discrepancy		X
78. Tumor Site discrepancy		X
79. Tumor Site discrepancy		X
80. Tumor Site discrepancy		X
81. Tumor Site discrepancy		X
82. Tumor Site discrepancy		X
83. Tumor Site discrepancy		X
84. Tumor Site discrepancy		X
85. Tumor Site discrepancy		X
86. Tumor Site discrepancy		X
87. Tumor Site discrepancy		X
88. Tumor Site discrepancy		X
89. Tumor Site discrepancy		X
90. Tumor Site discrepancy		X
91. Tumor Site discrepancy		X
92. Tumor Site discrepancy		X
93. Tumor Site discrepancy		X
94. Tumor Site discrepancy		X
95. Tumor Site discrepancy		X
96. Tumor Site discrepancy		X
97. Tumor Site discrepancy		X
98. Tumor Site discrepancy		X
99. Tumor Site discrepancy		X
100. Tumor Site discrepancy		X

Source: NCI Genomic Data Commons file ef97c526-0624-4152-bb3e-c6c4037c9461 (TCGA-CD-A4MJ.9FC598FF-9722-4179-80D7-909AE87A8688.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).